Somatic mutation profile of tumor specimen TCGA-N8-A4PI-01A (aliquot TCGA-N8-A4PI-01A-21D-A28R-08) from TCGA case TCGA-N8-A4PI, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Age at diagnosis: 71.9 years (26,270 days).
Specimen TCGA-N8-A4PI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91aa19e6-a703-4ec8-a3f7-b486488ac2a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N8-A4PI-10A (Blood Derived Normal), aliquot TCGA-N8-A4PI-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e11da54f-4cbf-4d14-bac7-fa05330d2f8a

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 12, Nonsense Mutation 6, Splice Site 3, Splice Region 2, Frame Shift Ins 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 59/133 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1357_1389del p.N453_Y463del (on ENST00000521381 / NM_181523.3; = p.N183_Y193del on NM_181504.4) | In Frame Del (DEL) | VAF 8/42 reads (19%) | hotspot (GDC flag); called by mutect2, pindel
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 41/53 reads (77%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 30/88 reads (34%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 50/91 reads (55%) | catalogued as rs1555525970, COSV52662121, COSV52858115, COSV53050787, COSV53082360; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DGKZ | c.2724C>T p.D908= (on ENST00000454345 / NM_001105540.2; = p.D720= on NM_003646.4) | Splice Region (SNP) | VAF 39/146 reads (27%) | catalogued as rs146211585; called by muse, mutect2, varscan2
- EPHA5 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56635210; called by muse, mutect2, varscan2
- F12 | c.447A>G p.I149M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV53693174; called by muse, mutect2, varscan2
- LIPT1 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778217082; called by muse, mutect2, varscan2
- MAPK4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs186595195, COSV68541012; called by muse, mutect2, varscan2
- NOVA1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.366); catalogued as rs1297018733; called by muse, mutect2, varscan2
- PCSK9 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as rs769000401, COSV56160563; called by muse, mutect2, varscan2
- PTPN23 | c.3143C>G p.P1048R | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99651114; called by muse, mutect2, varscan2
- SLAIN2 | c.1358C>A p.A453D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV99971603; called by muse, mutect2, varscan2
- USP53 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.551); catalogued as rs749089898, COSV56793922; called by muse, mutect2, varscan2
- AHNAK | c.9683T>C p.L3228P | Missense Mutation (SNP) | VAF 103/171 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ARHGAP5 | c.2773C>A p.H925N | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CBX5 | c.210T>A p.Y70* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- CHD4 | c.3332T>C p.L1111P (on ENST00000357008 / NM_001363606.2; = p.L1124P on NM_001273.5) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHD4 | c.558-1G>A p.X186_splice | Splice Site (SNP) | VAF 138/270 reads (51%) | called by muse, mutect2, varscan2
- CLCNKA | c.1504C>G p.L502V | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- CYP7B1 | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- DNAH5 | c.4257C>A p.Y1419* | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- FAM111A | c.1149T>G p.C383W | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM153A | c.702+1G>C p.X234_splice | Splice Site (SNP) | VAF 29/185 reads (16%) | called by muse, mutect2, varscan2
- H2AC4 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ILDR1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KDM4B | c.2450A>C p.H817P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LONRF3 | c.737T>G p.L246R | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- MYRIP | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR2T2 | c.741G>A p.M247I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4C3 | c.710C>G p.T237S | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- PIK3R1 | c.1259dup p.L420Ffs*22 (on ENST00000521381 / NM_181523.3; = p.L150Ffs*22 on NM_181504.4) | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | called by mutect2, pindel
- POLQ | c.451A>T p.K151* | Nonsense Mutation (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- PPP4R3B | c.2015T>A p.F672Y (on ENST00000616407 / NM_001122964.3; = p.F587Y on NM_020463.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RABL6 | c.582C>A p.F194L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAG1 | c.297G>A p.Q99= | Splice Region (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- SYCP2 | c.3544C>T p.P1182S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS4B | c.708T>G p.I236M | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- WNT9B | c.724T>A p.Y242N | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ZNF667 | c.405G>C p.K135N | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ZNF77 | c.1004G>A p.C335Y | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGEF10 | c.2502G>A p.T834= (on ENST00000398564; = p.T809= on NM_014629.4) | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs533238205, COSV50644991, COSV50663849; called by muse, mutect2, varscan2
- ARPP21 | c.1599G>A p.Q533= | Silent (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- C2orf16 | c.1800C>T p.I600= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs760184570, COSV62674483; called by muse, mutect2, varscan2
- CDK20 | c.663C>T p.G221= (on ENST00000325303 / NM_001039803.3; = p.G200= on NM_012119.4) | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as rs113461285; called by muse, mutect2, varscan2
- COL6A2 | c.2817C>T p.H939= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs368164391; called by muse, mutect2, varscan2
- CR1 | c.234C>T p.S78= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as rs142605009; called by muse, mutect2, varscan2
- GIMAP4 | c.150C>T p.I50= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- NTM | c.750A>C p.S250= | Silent (SNP) | VAF 78/158 reads (49%) | called by muse, mutect2, varscan2
- PRPF8 | c.4821G>A p.E1607= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- PTGFRN | c.999G>A p.R333= | Silent (SNP) | VAF 44/101 reads (44%) | called by muse, mutect2, varscan2
- RYR1 | c.5202C>T p.I1734= | Silent (SNP) | VAF 62/130 reads (48%) | catalogued as COSV62104399; called by muse, mutect2, varscan2
- SYDE2 | c.1128T>C p.P376= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502783 G>A | 5'Flank (SNP) | VAF 7/18 reads (39%) | called by muse, varscan2
